Gene-level copy-number profile of tumor specimen TCGA-2G-AAFG-01A from TCGA case TCGA-2G-AAFG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.1 years (11,002 days).
Specimen TCGA-2G-AAFG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.9bb35f24-2d25-45c3-9cd8-066524fe6bc9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAFG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2b5047c-6587-4693-bd1b-c1f7ef9c0c66

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,704; copy number 2: 15,910; copy number 3: 34,366; copy number 4: 5,512; copy number 5: 19; copy number 6: 1,316; copy number 7: 988.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAFG-01A-11D-A42X-01): tumor purity 0.45, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 988 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:72,558,744–75,528,148, 112 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:94,394,895–95,615,132, 26 genes, copy number 7 (within-gene range 6–7): COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1.
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
